CCDI case PBCIAR — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/cc6da2a6-3e2b-4276-a2b6-e1fa13f1f29c

Demographics
Sex at birth: female; Race: black or african american.

Diagnoses (1)
1. Carcinoma, NOS: ICD-O-3 morphology code: 8010/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 12.3 years (4,486 days).

Biospecimens (3 samples)
- Sample 0DSG1X: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DSG24: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DSG2L: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
